Surgical pathology report (de-identified scan), TCGA case TCGA-W2-A7H7, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Medical College of Wisconsin, specimen TCGA-W2-A7H7-01A (Primary Tumor).

[page 1 of 2]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

SURG PATH FINAL REPORT:

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

A. Left adrenal

Clinical Notes:

Pre-op diagnosis: Adrenal mass.

Diagnosis:

A. Adrenal mass, left, resection:

- Pheochromocytoma, see comment.
- Tumor focally extends to inked margin.

COMMENT (A): Sections show a fairly well circumscribed lesion that measures 3.2 cm in greatest dimension and is composed of small nests of cells within a vascular background. The neoplastic cells exhibit salt-and-pepper chromatin, with moderate cytologic pleomorphism, and rare multinucleation. There is no evidence of extra adrenal infiltration, vascular invasion, increased mitotic activity, or necrosis. Overall, these features favor a benign pheochromocytoma, but morphology does not also accurately predict tumor behavior.

(Electronically signed by)

Verified:

Gross:

A. The specimen is labeled "left adrenal." Received fresh is a 44 gram, 9.0 x 5.3 x 2.2 cm, portion of pink to yellow-tan soft tissue. The specimen is marked with black ink and serially sectioned to reveal a 6.0 x 3.7 x 2.4 cm adrenal gland with a 3.2 x 3.0 x 2.4 cm mass. The mass is soft and lobular, ranging from pale pink-gray to red-purple. The mass grossly appears to arise from the medulla, and is partially surrounded by a thin rim of bright orange adrenal cortex. Red-gray medulla is present within the adrenal

ICD-O-3

Pheochromocytoma NOS
8700/0

Site @ Adrenal gland NOS
C74.9

JW 9/4/13

[page 2 of 2]
[REDACTED]

gland on either end of the mass. The mass appears encapsulated, and the capsule abuts the black inked surface of the specimen. Portions of fresh tissue are submitted for tissue bank. Representative sections are submitted in cassettes A1 through A8.

Accession #:

Microscopic:
A histological examination has been performed.

Administrative Notes:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time

Lab Status
In process

Entered by

Source: NCI Genomic Data Commons file 910f683d-4f0b-47d6-b72b-69a00bf33bd6 (TCGA-W2-A7H7.030CB10F-9965-41BB-9ADA-29D56B55095F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).